Somatic mutation profile of tumor specimen TCGA-KK-A59Y-01A (aliquot TCGA-KK-A59Y-01A-11D-A26M-08) from TCGA case TCGA-KK-A59Y, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 56.9 years (20,768 days).
Specimen TCGA-KK-A59Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 540aefba-e967-4b52-9859-3b2a1ba947db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KK-A59Y-11A (Solid Tissue Normal), aliquot TCGA-KK-A59Y-11A-11D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c1d7c86-9d7f-4584-9efe-51fb28e413c7

The open-access MAF lists 23 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 5, Nonsense Mutation 2, Frame Shift Del 1, Intron 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC4 | c.1150C>T p.R384* | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | catalogued as rs1159726645, COSV65314425; called by muse, mutect2, varscan2
- CLCNKB | c.931A>T p.R311W | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV65161041; called by muse, mutect2, varscan2
- DAAM2 | c.3133C>T p.R1045C (on ENST00000274867 / NM_001201427.2; = p.R1044C on NM_015345.3) | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs772498031, COSV51347345; called by muse, mutect2, varscan2
- EGFR | c.934G>T p.G312W | Missense Mutation (SNP) | VAF 69/136 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV51814881; called by muse, mutect2, varscan2
- GALNT15 | c.271C>T p.R91W | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.53); catalogued as rs377515842; called by muse, mutect2, varscan2
- GRIN2B | c.3293C>T p.S1098F | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0.02); catalogued as COSV74205143, COSV74206547; called by muse, mutect2, varscan2
- MUC6 | c.2997C>A p.C999* | Nonsense Mutation (SNP) | VAF 15/40 reads (38%) | catalogued as COSV70144299; called by muse, mutect2, varscan2
- NELL1 | c.1402C>T p.R468C | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as rs371025282; called by muse, mutect2, varscan2
- NTN5 | c.777G>T p.W259C | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.645); catalogued as COSV54307769; called by muse, mutect2
- PHRF1 | c.2557G>A p.G853S (on ENST00000264555 / NM_001286581.2; = p.G852S on NM_020901.4) | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs201862192; called by muse, mutect2, varscan2
- RNF121 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs558215963, COSV62316820; called by muse, mutect2, varscan2
- SLC16A6 | c.1321G>A p.G441S | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59178081; called by muse, mutect2, varscan2
- SLC35E1 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs147619010; called by muse, mutect2, varscan2
- TMEM200C | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1242684903, COSV67309317; called by muse, mutect2, varscan2
- USH2A | c.2310del p.E771Kfs*17 | Frame Shift Del (DEL) | VAF 20/82 reads (24%) | catalogued as CD132739; called by mutect2, pindel, varscan2
- ZNF208 | c.694A>C p.K232Q | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.351); catalogued as COSV68108808, COSV68109287; called by muse, mutect2, varscan2
- CHD6 | c.725_730dup p.K243_R244insLK | In Frame Ins (INS) | VAF 78/274 reads (28%) | called by mutect2, pindel, varscan2
- ALKBH1 | c.21C>T p.A7= | Silent (SNP) | VAF 28/61 reads (46%) | catalogued as rs749200552, COSV53174402; called by muse, mutect2, varscan2
- CHRNA7 | c.1125G>A p.A375= | Silent (SNP) | VAF 26/103 reads (25%) | catalogued as rs201805261, COSV60972190; called by muse, mutect2, varscan2
- FAN1 | c.1113T>C p.G371= | Silent (SNP) | VAF 10/114 reads (9%) | catalogued as COSV62951126; called by muse, mutect2
- MEGF10 | c.2961C>T p.G987= | Silent (SNP) | VAF 11/91 reads (12%) | catalogued as rs373066612; called by muse, mutect2, varscan2
- ZNF628 | c.1650G>A p.T550= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs751531003, COSV52700497; called by muse, mutect2, varscan2
- RPL23 | c.97+60T>A | Intron (SNP) | VAF 16/57 reads (28%) | catalogued as COSV99834664; called by muse, mutect2, varscan2
